Somatic mutation profile of tumor specimen C3N-04277-02 (aliquot CPT0245400006) from CPTAC case C3N-04277, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 72.4 years (26,445 days).
Specimen C3N-04277-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97f54c15-8f5c-4820-8232-02494b2d8d5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04277-31 (Blood Derived Normal), aliquot CPT0245440002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f586c291-cc28-4e76-b885-322d1832690b

The open-access MAF lists 142 somatic variants for this specimen: 83 protein-altering or splice-affecting, 41 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 41, Intron 9, 5'UTR 3, RNA 3, 3'UTR 2, Frame Shift Ins 2, Nonsense Mutation 2, Frame Shift Del 2, Splice Site 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 45/297 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52666031, COSV52675881, COSV52731113, COSV52828604; called by muse, mutect2, varscan2
- ADAMTS7 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 64/692 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0.015); catalogued as COSV66309018; called by muse, mutect2
- CACNG7 | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 19/321 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.134); catalogued as rs1338129667; called by muse, mutect2
- CADPS | c.3109C>G p.L1037V | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs767902686; called by muse, mutect2, varscan2
- CREB3L2 | c.915G>T p.K305N | Missense Mutation (SNP) | VAF 34/376 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762334014, COSV57799514; called by muse, mutect2
- FAM184A | c.2871G>T p.K957N | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100138351; called by muse, mutect2
- GRIP1 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 36/444 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs377476830; ClinVar: uncertain significance; called by muse, mutect2
- HOXD9 | c.138G>T p.Q46H | Missense Mutation (SNP) | VAF 56/516 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.67); catalogued as COSV50896966; called by muse, mutect2, varscan2
- IGLL1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 84/944 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.044); catalogued as rs199906829; called by muse, mutect2
- KCNA3 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 30/362 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs766185334, COSV63900882; called by muse, mutect2
- KCNT1 | c.1496C>T p.A499V (on ENST00000488444; = p.A518V on NM_020822.3) | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs751063680; called by muse, mutect2
- MRC1 | c.4361C>T p.S1454L | Missense Mutation (SNP) | VAF 36/450 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1371563949; called by muse, mutect2
- PKHD1 | c.5282C>A p.S1761Y | Missense Mutation (SNP) | VAF 45/618 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV61887859; called by muse, mutect2
- RMND5A | c.989A>G p.Y330C | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs749759384; called by muse, mutect2, varscan2
- SEMA5B | c.2861C>T p.T954M | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs1560277290, COSV52094376; called by muse, mutect2
- SMURF1 | c.1522G>A p.G508R | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778974371; called by muse, mutect2, varscan2
- SPATA31D1 | c.3071C>A p.S1024Y | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.729); catalogued as COSV61192932; called by muse, mutect2, varscan2
- SUPV3L1 | c.2327C>T p.T776M | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as rs768961407, COSV100669924; called by muse, mutect2, varscan2
- TIGD3 | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 45/279 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.978); catalogued as rs772560955; called by muse, mutect2, varscan2
- TMEM44 | c.1235C>T p.S412L (on ENST00000392432 / NM_001166305.2; = p.S365L on NM_138399.5) | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.842); catalogued as rs373869816; called by muse, mutect2, varscan2
- TPBGL | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.03); catalogued as rs766337563; called by muse, mutect2
- TRIM51 | c.173C>A p.T58K | Missense Mutation (SNP) | VAF 26/321 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.039); catalogued as rs143686383; called by muse, mutect2
- TTYH2 | c.414G>C p.L138= | Splice Region (SNP) | VAF 16/196 reads (8%) | catalogued as COSV53910920; called by muse, mutect2
- TUBGCP4 | c.1114T>C p.F372L | Missense Mutation (SNP) | VAF 14/201 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1195787776; called by muse, mutect2
- VCPKMT | c.322A>G p.I108V | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.484); catalogued as rs928588077; called by muse, mutect2, varscan2
- ZBTB11 | c.1999C>T p.R667* | Nonsense Mutation (SNP) | VAF 18/173 reads (10%) | catalogued as COSV57244096; called by muse, mutect2, varscan2
- ZNF407 | c.5971G>A p.A1991T | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1178021697; called by muse, mutect2, varscan2
- ZNF493 | c.5A>G p.N2S | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as rs1322927392; called by muse, mutect2
- ZNF79 | c.1210C>T p.L404F | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.655); catalogued as COSV61070555; called by muse, mutect2, varscan2
- ABCB1 | c.2237A>T p.E746V | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.109); called by muse, mutect2
- ADGB | c.986A>G p.E329G | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- ADGRL1 | c.2450C>T p.S817L (on ENST00000340736 / NM_001008701.3; = p.S812L on NM_014921.5) | Missense Mutation (SNP) | VAF 35/516 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ANKMY2 | c.1097A>T p.K366M | Missense Mutation (SNP) | VAF 9/230 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2
- API5 | c.1459A>G p.K487E | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATRNL1 | c.2473G>A p.D825N | Missense Mutation (SNP) | VAF 14/205 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); called by muse, mutect2
- CCDC107 | c.410+1G>T p.X137_splice | Splice Site (SNP) | VAF 43/351 reads (12%) | called by muse, mutect2, varscan2
- CEP97 | c.1622T>C p.L541S | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2
- CLIP3 | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 49/373 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- CYP2W1 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 34/273 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCT | c.1058G>T p.G353V | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH14 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 51/516 reads (10%) | called by muse, mutect2, varscan2
- DNAJC14 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- DTNA | c.400A>G p.M134V | Missense Mutation (SNP) | VAF 32/320 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EHHADH | c.540A>C p.E180D | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.172); called by muse, mutect2
- ERV3-1 | c.1570A>G p.I524V | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); called by muse, mutect2
- FAT1 | c.6963G>C p.Q2321H | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2
- FAT1 | c.4283_4284del p.T1428Sfs*23 | Frame Shift Del (DEL) | VAF 36/222 reads (16%) | called by pindel, varscan2
- FMO4 | c.515dup p.H172Qfs*2 | Frame Shift Ins (INS) | VAF 22/197 reads (11%) | called by mutect2, varscan2
- FRY | c.8263A>T p.T2755S | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- GALNTL5 | c.510T>G p.I170M | Missense Mutation (SNP) | VAF 29/273 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GAS7 | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 35/253 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- GPRIN3 | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.049); called by muse, mutect2
- IARS2 | c.845T>G p.L282W | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IL13RA1 | c.1108C>G p.L370V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IRS1 | c.332T>C p.L111P | Missense Mutation (SNP) | VAF 25/243 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- KCNV2 | c.1280C>G p.A427G | Missense Mutation (SNP) | VAF 45/467 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- KIF22 | c.1919T>C p.I640T | Missense Mutation (SNP) | VAF 32/389 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.227); called by muse, mutect2
- LGMN | c.1120A>G p.T374A | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP3K6 | c.874G>T p.A292S | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- MTHFS | c.20G>C p.S7T | Missense Mutation (SNP) | VAF 42/387 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC16 | c.22948C>A p.H7650N | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- MYH8 | c.2143A>G p.R715G | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.192); called by muse, mutect2
- NDST4 | c.1330C>G p.Q444E | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NF1 | c.5621A>G p.Y1874C (on ENST00000358273 / NM_001042492.3; = p.Y1853C on NM_000267.3) | Missense Mutation (SNP) | VAF 13/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NLGN1 | c.2119G>A p.D707N | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PDE2A | c.1471G>A p.V491M | Missense Mutation (SNP) | VAF 40/480 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.158); called by muse, mutect2
- PHRF1 | c.246del p.L83Cfs*4 | Frame Shift Del (DEL) | VAF 38/321 reads (12%) | called by mutect2, pindel, varscan2
- PON1 | c.759T>A p.N253K | Missense Mutation (SNP) | VAF 24/364 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- PQBP1 | c.425_427del p.R142_E143delinsQ | In Frame Del (DEL) | VAF 35/237 reads (15%) | called by mutect2, pindel, varscan2
- PRAMEF4 | c.242A>G p.Q81R | Missense Mutation (SNP) | VAF 34/586 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.041); called by muse, mutect2
- RETNLB | c.153G>T p.K51N | Missense Mutation (SNP) | VAF 24/386 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.54); called by muse, mutect2
- RNF5 | c.442A>G p.T148A | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SAV1 | c.691C>T p.L231F | Missense Mutation (SNP) | VAF 24/267 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2
- SLFN14 | c.2648G>A p.C883Y | Missense Mutation (SNP) | VAF 39/382 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SYNRG | c.3494_3495insA p.Q1166Sfs*11 | Frame Shift Ins (INS) | VAF 10/102 reads (10%) | called by mutect2, varscan2
- TBC1D25 | c.1847C>T p.P616L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TNIK | c.1563C>A p.Y521* | Nonsense Mutation (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2
- TRIM64C | c.121C>T p.L41F | Missense Mutation (SNP) | VAF 61/557 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- TRRAP | c.8945C>A p.S2982Y (on ENST00000359863 / NM_001244580.1; = p.S2964Y on NM_003496.3) | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- TSTD1 | c.308A>G p.Y103C (on ENST00000423014 / NM_001113207.2; = p.Y62C on NM_001113206.2) | Missense Mutation (SNP) | VAF 24/370 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- TUBGCP6 | c.4052C>A p.A1351D | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.179); called by muse, mutect2
- USH2A | c.15086G>C p.G5029A | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- USP24 | c.7703A>G p.Y2568C | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2
- ATOX1 | c.78T>G p.L26= | Silent (SNP) | VAF 31/185 reads (17%) | called by muse, mutect2, varscan2
- B4GALNT4 | c.2659C>A p.R887= | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, varscan2
- BDP1 | c.1836G>A p.L612= | Silent (SNP) | VAF 38/188 reads (20%) | called by muse, mutect2, varscan2
- CAPN15 | c.498C>T p.C166= | Silent (SNP) | VAF 22/264 reads (8%) | catalogued as rs756523736; called by muse, mutect2
- DMBT1 | c.3177T>C p.D1059= (on ENST00000338354 / NM_001377530.1; = p.D560= on NM_004406.3) | Silent (SNP) | VAF 74/798 reads (9%) | called by muse, mutect2
- DMRTC2 | c.615G>A p.L205= | Silent (SNP) | VAF 32/348 reads (9%) | called by muse, mutect2
- DPT | c.159G>A p.G53= | Silent (SNP) | VAF 67/672 reads (10%) | called by muse, mutect2
- DTX2 | c.1698G>A p.T566= | Silent (SNP) | VAF 13/422 reads (3%) | catalogued as rs368665521; called by muse, mutect2
- EP400 | c.7653G>A p.Q2551= | Silent (SNP) | VAF 33/209 reads (16%) | called by muse, mutect2, varscan2
- FAM110B | c.303C>T p.F101= | Silent (SNP) | VAF 74/527 reads (14%) | catalogued as rs368594517, COSV100826122; called by muse, mutect2, varscan2
- GDA | c.648C>G p.L216= | Silent (SNP) | VAF 12/163 reads (7%) | called by muse, mutect2
- KCNT1 | c.1086C>G p.L362= (on ENST00000488444; = p.L381= on NM_020822.3) | Silent (SNP) | VAF 16/254 reads (6%) | called by muse, mutect2
- LALBA | c.201G>A p.T67= | Silent (SNP) | VAF 28/252 reads (11%) | catalogued as rs753946024, COSV56395724, COSV99974382; called by muse, mutect2
- LAS1L | c.822A>G p.V274= | Silent (SNP) | VAF 19/134 reads (14%) | called by muse, mutect2, varscan2
- LRRC1 | c.834C>T p.L278= | Silent (SNP) | VAF 13/157 reads (8%) | called by muse, mutect2
- MDN1 | c.13716G>A p.Q4572= | Silent (SNP) | VAF 14/166 reads (8%) | called by muse, mutect2
- MRPS2 | c.804G>A p.E268= | Silent (SNP) | VAF 41/429 reads (10%) | called by muse, mutect2
- MTHFS | c.21C>T p.S7= | Silent (SNP) | VAF 43/394 reads (11%) | called by muse, mutect2, varscan2
- MUC17 | c.6867G>A p.T2289= | Silent (SNP) | VAF 14/161 reads (9%) | catalogued as rs775448898, COSV60287154; called by muse, mutect2
- MYO9B | c.5046C>G p.S1682= | Silent (SNP) | VAF 17/227 reads (7%) | catalogued as rs758590931; called by muse, mutect2
- MYT1 | c.1203G>T p.P401= | Silent (SNP) | VAF 27/378 reads (7%) | called by muse, mutect2
- NLRC5 | c.4533C>T p.L1511= | Silent (SNP) | VAF 26/382 reads (7%) | catalogued as rs752787505; called by muse, mutect2
- OR2L13 | c.690G>A p.K230= | Silent (SNP) | VAF 24/298 reads (8%) | called by muse, mutect2
- OR6K6 | c.6G>A p.K2= | Silent (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2
- PCDH10 | c.1383G>C p.P461= | Silent (SNP) | VAF 22/340 reads (6%) | catalogued as COSV52093699; called by muse, mutect2
- POLR2J2 | c.81C>T p.P27= | Silent (SNP) | VAF 108/1350 reads (8%) | called by muse, mutect2
- PPIL2 | c.42C>G p.T14= | Silent (SNP) | VAF 30/251 reads (12%) | catalogued as COSV100622700; called by muse, mutect2, varscan2
- PPP3R2 | c.186C>T p.F62= | Silent (SNP) | VAF 17/219 reads (8%) | catalogued as rs868308424, COSV62452567; called by muse, mutect2
- PRMT8 | c.675G>A p.A225= | Silent (SNP) | VAF 37/436 reads (8%) | catalogued as rs151263603; called by muse, mutect2
- PUS1 | c.846C>T p.I282= | Silent (SNP) | VAF 64/481 reads (13%) | called by muse, mutect2, varscan2
- RAPGEF5 | c.849C>T p.A283= | Silent (SNP) | VAF 15/323 reads (5%) | catalogued as rs542526589; called by muse, mutect2
- RBL1 | c.804G>A p.E268= | Silent (SNP) | VAF 10/196 reads (5%) | catalogued as rs1401153022; called by muse, mutect2
- RIMKLA | c.903C>G p.S301= | Silent (SNP) | VAF 41/379 reads (11%) | called by muse, mutect2, varscan2
- RNF25 | c.897C>T p.A299= | Silent (SNP) | VAF 26/264 reads (10%) | catalogued as rs202163379, COSV99828826; called by muse, mutect2
- SCNN1B | c.945G>T p.G315= | Silent (SNP) | VAF 33/296 reads (11%) | called by muse, mutect2, varscan2
- SELENON | c.489G>A p.Q163= | Silent (SNP) | VAF 54/484 reads (11%) | called by muse, mutect2, varscan2
- SERPINB6 | c.666A>G p.Q222= (on ENST00000612421 / NM_001271823.2; = p.Q203= on NM_004568.6) | Silent (SNP) | VAF 40/400 reads (10%) | called by muse, mutect2
- SLC24A5 | c.228C>T p.I76= | Silent (SNP) | VAF 37/418 reads (9%) | catalogued as rs762176351, COSV58316211; called by muse, mutect2
- SYMPK | c.2427G>A p.A809= | Silent (SNP) | VAF 28/534 reads (5%) | catalogued as rs747848815; called by muse, mutect2
- TAF15 | c.1680A>G p.G560= (on ENST00000605844 / NM_139215.3; = p.G557= on NM_003487.4) | Silent (SNP) | VAF 17/238 reads (7%) | catalogued as rs764692726; called by muse, mutect2
- TDRD12 | c.234C>A p.V78= | Silent (SNP) | VAF 52/260 reads (20%) | called by muse, mutect2, varscan2
- AC136628.2 | n.684C>G | RNA (SNP) | VAF 43/447 reads (10%) | called by muse, mutect2, varscan2
- AK2 | c.*721C>T | 3'UTR (SNP) | VAF 11/108 reads (10%) | called by muse, mutect2
- CRB1 | c.4006-88G>A | Intron (SNP) | VAF 27/346 reads (8%) | called by muse, mutect2
- EPHA6 | c.2784+8137G>T | Intron (SNP) | VAF 25/255 reads (10%) | called by muse, mutect2, varscan2
- GALNS | c.120+1363C>T | Intron (SNP) | VAF 20/195 reads (10%) | called by muse, mutect2, varscan2
- GPT2 | c.-2C>T | 5'UTR (SNP) | VAF 5/41 reads (12%) | catalogued as rs749695994; called by mutect2, varscan2
- IL1RL2 | c.-30C>T | 5'UTR (SNP) | VAF 24/278 reads (9%) | called by muse, mutect2
- LRRC53 | c.-5C>T | 5'UTR (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640686 A>T | 3'Flank (SNP) | VAF 33/416 reads (8%) | called by muse, mutect2
- MIR518A1 | n.84G>C | RNA (SNP) | VAF 11/147 reads (7%) | called by muse, mutect2
- NOP56 | c.570-181A>G | Intron (SNP) | VAF 34/303 reads (11%) | called by muse, mutect2, varscan2
- NTM-AS1 | n.2309C>T | RNA (SNP) | VAF 42/222 reads (19%) | catalogued as rs560199078; called by muse, mutect2, varscan2
- PHC2 | c.1555+4623C>T | Intron (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- PUM1 | c.363+3865C>T | Intron (SNP) | VAF 10/130 reads (8%) | catalogued as rs564917441; called by muse, mutect2
- RREB1 | c.3809-5966C>G | Intron (SNP) | VAF 18/146 reads (12%) | catalogued as COSV58556273; called by muse, varscan2
- UBE2D3 | c.398+432A>G | Intron (SNP) | VAF 22/176 reads (13%) | catalogued as rs762394601; called by muse, mutect2, varscan2
- ZNF497 | c.-111-706C>T | Intron (SNP) | VAF 40/144 reads (28%) | called by muse, mutect2, varscan2
- ZNF827 | c.*278G>T | 3'UTR (SNP) | VAF 37/418 reads (9%) | called by muse, mutect2
